Somatic mutation profile of tumor specimen BA3435D (aliquot aq-BA3435D) from BEATAML1.0 case 2613, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 79.4 years (29,002 days).
Specimen BA3435D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96967f23-7caa-4bc9-a435-fb3a89a88d3b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3366D (Solid Tissue Normal), aliquot aq-BA3366D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd2a95ee-77c8-4e1a-b765-69ba8e796b4d

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.1849G>T p.V617F | Missense Mutation (SNP) | VAF 11/156 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs77375493, CM123094, COSV67569051, COSV67571909; ClinVar: risk factor / pathogenic / likely pathogenic / not provided / affects; called by muse, mutect2
- GRIN3A | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2
- KIAA1755 | c.2492A>G p.N831S | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FYCO1 | c.3768C>T p.A1256= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as rs750693529; called by muse, mutect2, varscan2
